Somatic mutation profile of tumor specimen C3N-01756-01 (aliquot CPT0163160006) from CPTAC case C3N-01756, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.7 years (22,915 days).
Specimen C3N-01756-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21d2fc5d-e469-477d-a9f0-0bd229da9c2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01756-31 (Blood Derived Normal), aliquot CPT0163200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95cea166-98a6-423b-941a-946c26a0efba

The open-access MAF lists 129 somatic variants for this specimen: 85 protein-altering or splice-affecting, 25 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 25, Intron 9, Nonsense Mutation 5, Frame Shift Ins 4, 5'UTR 4, RNA 3, Frame Shift Del 3, 3'UTR 2, Splice Region 2, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RNF43 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | hotspot (GDC flag); catalogued as rs1458799446, COSV68456834; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 151/206 reads (73%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1214039038; called by muse, mutect2, varscan2
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2, varscan2
- BRSK1 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs773276955; called by muse, mutect2, varscan2
- C4orf54 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs752655126; called by muse, mutect2, varscan2
- CCDC136 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 150/347 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs1311365591, COSV99922289; called by muse, mutect2, varscan2
- CDH11 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556647809, COSV51756679, COSV51758059; called by muse, mutect2, varscan2
- CDH8 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1467267983, COSV54868573; called by muse, mutect2, varscan2
- CENPB | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 154/281 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV60147959; called by muse, varscan2
- CEP250 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780172188; called by muse, mutect2, varscan2
- DCAF4 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs540271702; called by muse, mutect2, varscan2
- EOLA2 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1557374763, COSV62207378; called by muse, mutect2, varscan2
- HYAL4 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56138259, COSV56138709; called by muse, mutect2, varscan2
- OR2T11 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58185567, COSV58187562; called by muse, mutect2
- PIP5K1C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 79/513 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs773061807; called by muse, mutect2, varscan2
- SPATA5 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs1251932014; called by muse, mutect2, varscan2
- SPHKAP | c.2118G>A p.M706I | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60896212; called by muse, mutect2, varscan2
- STK11 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs587782364, COSV53071079; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SUFU | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV64014466; called by muse, mutect2
- UBXN6 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs374004344; called by muse, mutect2, varscan2
- XPOT | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as COSV60347877; called by muse, mutect2, varscan2
- AC008397.2 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); called by muse, mutect2
- AC011005.1 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 20/695 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATXN1 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CDYL2 | c.587A>T p.N196I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by mutect2, varscan2
- CEACAM20 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.724); called by muse, varscan2
- CENPA | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2
- CFAP61 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- CNST | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 90/122 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCLRE1B | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 135/280 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAJC17 | c.406_410del p.S136Afs*18 | Frame Shift Del (DEL) | VAF 123/348 reads (35%) | called by mutect2, pindel, varscan2
- F9 | c.1090A>T p.R364* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2
- GALNT9 | c.658A>C p.S220R | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2
- GBF1 | c.3468C>A p.F1156L (on ENST00000369983 / NM_001377137.1; = p.F1155L on NM_004193.3) | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GPR142 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GPR156 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- GRB7 | c.1533C>A p.F511L | Missense Mutation (SNP) | VAF 235/8601 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- H2AC13 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.143); called by muse, varscan2
- HOXA1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- IFT172 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- IP6K2 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT tolerated (0.76); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ITGB8 | c.1594T>A p.S532T | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCORL | c.836T>C p.L279S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LIMCH1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MINDY2 | c.1329C>G p.F443L | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MTMR6 | c.1108A>C p.K370Q | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.38047G>C p.G12683R | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MYOM2 | c.805T>A p.S269T | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- MYOM2 | c.2392G>T p.D798Y | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NAA40 | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NAV2 | c.3393C>A p.S1131R (on ENST00000396087 / NM_001244963.2; = p.S1108R on NM_145117.5) | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NOP16 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 129/217 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPHS1 | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 101/253 reads (40%) | called by muse, mutect2, varscan2
- OBSL1 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 133/614 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP3 | c.1346_1347del p.E449Afs*29 | Frame Shift Del (DEL) | VAF 144/329 reads (44%) | called by pindel, varscan2
- PCDHB15 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLEC | c.2871G>T p.V957= (on ENST00000322810 / NM_201380.4; = p.V847= on NM_000445.5) | Splice Region (SNP) | VAF 85/1024 reads (8%) | called by muse, mutect2
- PPP1R9A | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- PRELID1 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- RAB11FIP3 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 244/440 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SLC46A1 | c.1323-8T>A | Splice Region (SNP) | VAF 152/326 reads (47%) | called by muse, mutect2, varscan2
- SLC7A10 | c.379G>C p.V127L | Missense Mutation (SNP) | VAF 109/400 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- SP1 | c.1580C>T p.P527L (on ENST00000327443 / NM_138473.3; = p.P520L on NM_003109.1) | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SPAG17 | c.6580C>T p.Q2194* | Nonsense Mutation (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- SPATA5 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 154/405 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TIAM1 | c.2723C>T p.S908F | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLR6 | c.482_483insG p.D162Rfs*26 | Frame Shift Ins (INS) | VAF 62/130 reads (48%) | called by mutect2, varscan2
- TLR6 | c.480dup p.L161Ifs*27 | Frame Shift Ins (INS) | VAF 59/187 reads (32%) | called by mutect2*, pindel, varscan2*
- TMA16 | c.37dup p.E13Gfs*9 | Frame Shift Ins (INS) | VAF 16/168 reads (10%) | called by mutect2, pindel
- TMEM242 | c.179G>A p.W60* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- TNRC6B | c.5081A>G p.Q1694R (on ENST00000454349 / NM_001162501.2; = p.Q1584R on NM_015088.3) | Missense Mutation (SNP) | VAF 95/237 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRIOBP | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPA1 | c.226dup p.I76Nfs*2 | Frame Shift Ins (INS) | VAF 28/177 reads (16%) | called by mutect2, pindel, varscan2
- TSC22D1 | c.2009G>C p.G670A | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.007); called by muse, mutect2
- TSR1 | c.1912C>G p.H638D | Missense Mutation (SNP) | VAF 140/176 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TUBGCP6 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 148/558 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by mutect2, varscan2
- USP5 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 128/183 reads (70%) | SIFT tolerated (0.65); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- USP9X | c.1086A>G p.I362M | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- XPOT | c.1877A>T p.E626V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- Z83844.2 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 164/363 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF134 | c.995T>A p.I332N | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.377); called by muse, mutect2
- ZNF483 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF749 | c.202del p.V68Cfs*14 | Frame Shift Del (DEL) | VAF 35/91 reads (38%) | called by mutect2, pindel*, varscan2*
- ATXN1 | c.702C>T p.I234= | Silent (SNP) | VAF 60/547 reads (11%) | called by muse, mutect2, varscan2
- BUD23 | c.21T>G p.R7= | Silent (SNP) | VAF 90/428 reads (21%) | called by muse, mutect2, varscan2
- COL5A1 | c.1515C>T p.G505= | Silent (SNP) | VAF 281/459 reads (61%) | catalogued as COSV65669201; called by muse, mutect2, varscan2
- CXCL11 | c.57T>C p.V19= | Silent (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2, varscan2
- DMWD | c.1437C>T p.G479= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs770102643; called by muse, mutect2, varscan2
- DNHD1 | c.7789C>T p.L2597= | Silent (SNP) | VAF 55/259 reads (21%) | catalogued as rs769916649; called by muse, mutect2, varscan2
- DOK3 | c.330C>T p.H110= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs752160007; called by muse, mutect2
- FREM3 | c.1377C>A p.I459= | Silent (SNP) | VAF 43/239 reads (18%) | called by muse, mutect2, varscan2
- GAA | c.1245G>A p.T415= | Silent (SNP) | VAF 26/484 reads (5%) | catalogued as rs760920034, COSV100163443; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- MCUR1 | c.24C>A p.G8= | Silent (SNP) | VAF 28/403 reads (7%) | called by muse, mutect2
- MED30 | c.162C>T p.L54= | Silent (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- MICAL2 | c.1617C>T p.T539= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as rs372942983; called by muse, mutect2, varscan2
- PAPOLB | c.1224G>A p.K408= | Silent (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- PCDHB5 | c.960C>T p.A320= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1554275895; called by muse, mutect2, varscan2
- PCDHGA2 | c.1137C>T p.N379= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs756410712, COSV53930982; called by muse, mutect2, varscan2
- PLCE1 | c.6333C>A p.T2111= | Silent (SNP) | VAF 100/459 reads (22%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.702C>A p.T234= | Silent (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- PTPRK | c.4002G>A p.Q1334= (on ENST00000368215 / NM_001291984.2; = p.Q1335= on NM_002844.4) | Silent (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- RANBP2 | c.501G>A p.V167= | Silent (SNP) | VAF 226/591 reads (38%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.381C>T p.S127= | Silent (SNP) | VAF 138/347 reads (40%) | called by muse, mutect2, varscan2
- SRPK2 | c.630C>A p.I210= | Silent (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- SYNC | c.39C>T p.A13= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- UBA1 | c.3051G>A p.E1017= | Silent (SNP) | VAF 257/355 reads (72%) | catalogued as rs1556794719; called by muse, mutect2, varscan2
- WRAP73 | c.567C>T p.N189= | Silent (SNP) | VAF 127/389 reads (33%) | catalogued as rs549533945, COSV54560898; called by muse, mutect2, varscan2
- ZNF692 | c.81C>T p.C27= | Silent (SNP) | VAF 87/124 reads (70%) | catalogued as rs1205066567; called by muse, mutect2, varscan2
- AAAS | c.1331+25T>C | Intron (SNP) | VAF 259/610 reads (42%) | called by muse, mutect2, varscan2
- ACE | c.2218-18C>A | Intron (SNP) | VAF 288/543 reads (53%) | called by muse, mutect2, varscan2
- BSCL2 | c.-11C>G | 5'UTR (SNP) | VAF 20/150 reads (13%) | called by muse, varscan2
- CSMD2 | c.67+778G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs1213821852; called by muse, mutect2
- ITGA4 | c.*1415G>A | 3'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs1035779710; called by muse, mutect2, varscan2
- LINC02118 | n.137C>T | RNA (SNP) | VAF 9/200 reads (5%) | catalogued as rs971778907; called by muse, mutect2
- LY9 | c.454+1825G>A | Intron (SNP) | VAF 119/166 reads (72%) | catalogued as COSV54434363; called by muse, mutect2, varscan2
- MIR3150B | chr8:95075712 G>C | 5'Flank (SNP) | VAF 13/254 reads (5%) | called by muse, mutect2
- PDIA3P1 | n.1536G>A | RNA (SNP) | VAF 24/293 reads (8%) | catalogued as rs781915943; called by muse, mutect2
- PLEKHB2 | c.424-65569C>A | Intron (SNP) | VAF 52/84 reads (62%) | called by muse, mutect2, varscan2
- PPIL2 | c.33-567G>A | Intron (SNP) | VAF 13/103 reads (13%) | catalogued as rs761088439; called by muse, mutect2, varscan2
- PPP2R2C | c.71-1364G>A | Intron (SNP) | VAF 79/421 reads (19%) | catalogued as rs776299978; called by muse, mutect2, varscan2
- SF3B2 | c.549+15C>T | Intron (SNP) | VAF 29/151 reads (19%) | catalogued as rs1289562608; called by muse, mutect2, varscan2
- SNORD115-42 | n.39G>T | RNA (SNP) | VAF 65/527 reads (12%) | called by muse, mutect2, varscan2
- TFAM | c.-45G>T | 5'UTR (SNP) | VAF 98/201 reads (49%) | called by muse, mutect2, varscan2
- TFAM | c.-44C>T | 5'UTR (SNP) | VAF 103/206 reads (50%) | called by muse, mutect2, varscan2
- TRPM1 | c.724+1040C>G | Intron (SNP) | VAF 23/145 reads (16%) | catalogued as COSV99855995; called by muse, mutect2, varscan2
- UNC5D | c.*2437C>G | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
- ZNF415 | c.-2A>T | 5'UTR (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
